Surgical pathology report (de-identified scan), TCGA case TCGA-51-6867, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-51-6867-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A: Lung, right upper lobe, wedge resection.

- Invasive moderately differentiated squamous cell carcinoma, tumor size 2.0 cm in greatest dimension (see comment).
- Surgical margins free of tumor.

B: Lymph node, R4, removal.

- No tumor seen in two lymph nodes (0/2).

Comment:

This patient has a history of a prior laryngeal T4 squamous cell carcinoma. We have reviewed the tumor in the lung and the tumor of the larynx, and the tumors appear similar, with the laryngeal tumor showing slightly less squamous differentiation. It is not possible to determine if the tumor in the lung represents metastatic disease or a new primary. Review of the clinical workstation reveals that the multidisciplinary thoracic oncology conference favored a new primary lung cancer.

Clinical History:

The patient is a [REDACTED]-year-old female with right upper lobe lesion.

Gross Description:

Received are two appropriately labeled containers.

Container A is additionally labeled "RUL wedge resection."

Specimen fixation: formalin

Type of specimen/parts of lung received: right upper lobe wedge resection

Size of specimen: 10 x 4.8 x 1.5 cm

Weight of specimen: 38.7 grams

Other attached structures: n/a

[page 2 of 3]
Tumor location: peripheral

Tumor size: There is a complex staple line running the length of the specimen;

there is a 1.4 cm pleural disruption (2.4 cm from closest staple line) and a 0.6 cm

second pleural disruption which is 0.3 cm from the larger disrupted area (1.0 cm to

staple line). The pleural is red/tan and mottled. The staple line is inked blue, the

pleural is inked yellow and the disrupted areas are outlined in yellow. Sectioning

exhibits a 2 x approximately 1.3 x 0.6 cm tan, firm nodule with scalloped/lobulated

borders which is immediately beneath the largest disrupted site. Immediately

adjacent to the noted nodule, there is a cavitory, necrotic area which is believed

to be necrotic nodule.

Relationship of tumor to bronchus: n/a

Distance of tumor to bronchial margin: n/a

Relationship/distance of tumor to pleura: approximately 0.6 cm, however, the nodule

is immediately beneath a disrupted site

Distance of tumor to other surgical margins: 1.0 cm

Presence/absence of satellite tumor nodules: absent

Involvement of attached structures by tumor: n/a

Description of nontumorous lung: the remainder of the lung parenchyma is dark

red/tan, soft, spongy and aerated;

no other lesions, masses, or abnormalities are identified

Comment: A small slice of tumor and a small slice of normal was given to Tissue

Procurement.

[page 3 of 3]
Block Summary:

- A1 - staple line closest to nodule
- A2 - nodule
- A3 - cavity necrotic area
- A4 - additional tumor and adjacent lung parenchyma
- A5 - uninvolved lung

Container B is additionally labeled "R-4 lymph node." It holds a 2.3 x 2.0 x 0.5 cm aggregate of two fragments, one large and one small, of red/gray, focally cauterized lymphoid tissue which are submitted in block B1, NTR.

Light Microscopy:

Light microscopic examination is performed by Dr.

Tumor histologic type (WHO classification): squamous cell carcinoma

Tumor histologic grade (WHO classification): moderately differentiated

Tumor size (greatest dimension): 2.0 cm

Histologic assessment of surgical margins: surgical margins free of tumor

Pleural involvement: not identified

In situ carcinoma: not identified

Invasion:

angiolymphatic - not identified

perineural - not identified

Lymph nodes (by node group): no tumor seen in 2 R4 lymph nodes (0/2)

Findings in nontumorous lung: emphysematous changes

Source: NCI Genomic Data Commons file 8576cd35-c27f-4ed4-855b-894c82822bbc (TCGA-51-6867.6EB25B3D-1446-47F3-B52E-E97157F4832F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).